TCGA case TCGA-KD-A5QU — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Uterus, NOS; Tissue source site: Mount Sinai School of Medicine. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/02b7b0c5-dad6-4270-b56b-3d04285e8147

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 41 years; Vital status: Dead; Days to death: 1,073 days (2.9 years).

Diagnoses (2)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C55; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Uterus, NOS; Classification of tumor: primary; Age at diagnosis: 41.1 years (15,018 days); Year of diagnosis: 2010; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Uterus.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis present: Yes.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 9.
2. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Lung, NOS. Age at diagnosis: 44.0 years (16,078 days); Days to diagnosis: 1,060 days (2.9 years); Prior treatment: Yes.

Follow-up (3 entries)
- Days to follow up: 259 days; Disease response: Tumor Free.
- Day 1,060 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 1,060 days (2.9 years).
- Days to follow up: 1,073 days (2.9 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 28.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-KD-A5QU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 20 mg.
  Slide TCGA-KD-A5QU-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-KD-A5QU-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Poorly differentiated or pleomorphic or epithelioid leiomyosarcoma; Site of primary tumor other: Myometrium; Margin status: Negative; Tumor total necrosis: Moderate Necrosis (>=10, <50%); Contiguous organ invaded: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Gynecological - Uterus; Submitted tumor site: Gynecological - Other (please specify.
- Primary pathology, Tumor sizes, Tumor size: Lesion pathologic length: 9.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.
- Drug treatment 1: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 93; Days from index date to pharmaceutical treatment ended: 219; Pharmaceutical therapy drug name: Gemzar; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Complete Response.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 2: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 93; Days from index date to pharmaceutical treatment ended: 219; Pharmaceutical therapy drug name: Cisplatin; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Complete Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,073 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,073 days; disease-free interval: event (new tumor event after initially disease-free), 1,060 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,060 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-KD-A5QU-01A-11D-A27O-01): tumor purity 0.93, ploidy 1.5, whole-genome doublings 0.
